Somatic mutation profile of tumor specimen 0DO5FK from CCDI case PBBVBJ, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Primary diagnosis: Pilocytic astrocytoma; Tissue or organ of origin: Parietal lobe; Age at diagnosis: 16.9 years (6,187 days).
Specimen 0DO5FK: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 199150de-53cc-4f73-b16e-39d74950e4e0.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DO5DV (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/69477447-2fd5-456e-aa34-8b3f664552ec

The open-access MAF lists 21 somatic variants for this specimen: 13 protein-altering or splice-affecting, 2 silent, 6 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 12, Intron 4, 3'UTR 2, Silent 2, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CDC6 | c.1667C>T p.A556V | Missense Mutation (SNP) | VAF 88/998 reads (9%) | SIFT deleterious (0.04); PolyPhen benign (0.1); catalogued as rs752200069; called by muse, mutect2
- IRGC | c.179C>T p.T60M | Missense Mutation (SNP) | VAF 23/209 reads (11%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.995); catalogued as rs755942419; called by muse, mutect2, varscan2
- MORC1 | c.353C>T p.T118M | Missense Mutation (SNP) | VAF 142/1484 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs762624333, COSV51722702; called by muse, mutect2
- MUC7 | c.1072C>T p.R358* | Nonsense Mutation (SNP) | VAF 146/1944 reads (8%) | catalogued as rs774737670, COSV59218760; called by muse, mutect2
- PIEZO2 | c.3400G>A p.V1134I | Missense Mutation (SNP) | VAF 191/623 reads (31%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.972); catalogued as rs771172115; called by muse, mutect2, varscan2
- TAS1R2 | c.1534G>A p.V512I | Missense Mutation (SNP) | VAF 48/644 reads (7%) | SIFT tolerated (0.22); PolyPhen benign (0); catalogued as rs775169550, COSV64744979; called by muse, mutect2
- TRPC4 | c.2872G>C p.D958H (on ENST00000379705 / NM_016179.4; = p.D963H on NM_003306.3) | Missense Mutation (SNP) | VAF 92/1428 reads (6%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.388); catalogued as COSV59022019; called by muse, mutect2
- DOCK9 | c.5287G>A p.A1763T (on ENST00000376460 / NM_001366676.2; = p.A1764T on NM_015296.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 42/658 reads (6%) | SIFT deleterious (0); PolyPhen benign (0.439); called by muse, mutect2
- ITGA7 | c.493G>A p.V165M | Missense Mutation (SNP) | VAF 52/608 reads (9%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.564); called by muse, mutect2
- KLHDC2 | c.1067T>G p.I356R | Missense Mutation (SNP) | VAF 74/1320 reads (6%) | SIFT deleterious (0); PolyPhen benign (0.047); called by muse, mutect2
- PIK3CG | c.2197A>G p.T733A | Missense Mutation (SNP) | VAF 127/1243 reads (10%) | SIFT tolerated (0.56); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- SIGLEC10 | c.1925A>T p.Q642L | Missense Mutation (SNP) | VAF 28/482 reads (6%) | SIFT tolerated (0.71); PolyPhen benign (0); called by muse, mutect2
- TM4SF1 | c.505C>T p.L169F | Missense Mutation (SNP) | VAF 97/1542 reads (6%) | SIFT tolerated (0.22); PolyPhen benign (0.028); called by muse, mutect2
- ANKRD30A | c.495C>T p.I165= (on ENST00000611781; = p.I109= on NM_052997.2) | Silent (SNP) | VAF 145/1390 reads (10%) | catalogued as rs200101337, COSV64618579; called by muse, mutect2, varscan2
- RAB11FIP1 | c.2901G>A p.S967= | Silent (SNP) | VAF 23/405 reads (6%) | catalogued as rs1163400210, COSV54762261, COSV54764671; called by muse, mutect2
- CEP131 | c.1024-59C>T | Intron (SNP) | VAF 17/132 reads (13%) | catalogued as COSV53953287; called by muse, mutect2
- GTPBP4 | c.460+60T>C | Intron (SNP) | VAF 9/114 reads (8%) | called by muse, mutect2
- MICAL1 | c.1945-24T>C | Intron (SNP) | VAF 15/250 reads (6%) | called by muse, mutect2
- SERPINA7 | c.1045-12C>T | Intron (SNP) | VAF 45/395 reads (11%) | called by muse, mutect2, varscan2
- TNFRSF21 | c.*16C>T | 3'UTR (SNP) | VAF 221/515 reads (43%) | called by muse, mutect2, varscan2
- UBAC2 | c.*80C>T | 3'UTR (SNP) | VAF 8/110 reads (7%) | catalogued as rs1047144074; called by muse, mutect2
